Somatic mutation profile of tumor specimen MP2PRT-PASNHU-TMP1-A (aliquot MP2PRT-PASNHU-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNHU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,400 days).
Specimen MP2PRT-PASNHU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69bc33b9-d338-4d84-9b35-fea77743e0b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNHU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNHU-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/511ce90a-8c5d-435c-886e-b25243322fbe

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGB | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 175/668 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs571624045, COSV57418511, COSV57419244; called by muse, mutect2, varscan2
- SLC1A1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs761430315, COSV52052108; called by muse, mutect2, varscan2
- CCNH | c.760+1_760+2insGGAC p.X254_splice | Splice Site (INS) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- ECT2 | c.871G>T p.E291* (on ENST00000392692 / NM_001349098.2; = p.E260* on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | called by muse, varscan2
- SYT14 | c.1123del p.M375Cfs*5 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by pindel, varscan2
- CFAP92 | c.378C>T p.D126= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as rs758796821; called by muse, mutect2, varscan2
- IGHE | c.1122G>A p.T374= | Silent (SNP) | VAF 251/1448 reads (17%) | catalogued as rs782062051; called by muse, mutect2, varscan2
